Somatic mutation profile of tumor specimen ALCH-B0H6-TTP1-A (aliquot ALCH-B0H6-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-B0H6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.5 years (20,627 days).
Specimen ALCH-B0H6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ec999d0-4a26-4783-87c5-ad288b44f850.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0H6-NB1-A (Blood Derived Normal), aliquot ALCH-B0H6-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1ea35ba-e018-4f58-a956-c7e16d3dd1bf

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 5, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD3 | c.692C>G p.P231R | Missense Mutation (SNP) | VAF 57/536 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52308297; called by muse, mutect2, varscan2
- IGFBPL1 | c.633A>G p.I211M | Missense Mutation (SNP) | VAF 17/245 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.13); catalogued as rs1176609999; called by muse, mutect2
- MC3R | c.641C>A p.A214E | Missense Mutation (SNP) | VAF 343/1096 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568966650; called by muse, mutect2, varscan2
- MUC12 | c.9157C>T p.P3053S (on ENST00000379442; = p.P2910S on NM_001164462.1) | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.955); catalogued as rs113645398, COSV65208736; called by muse, mutect2
- NEK11 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs772478508; called by muse, mutect2
- PEAR1 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 44/514 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs945115143; called by muse, mutect2
- PIGZ | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 52/484 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757183486; called by muse, mutect2
- ALMS1 | c.2154T>A p.H718Q | Missense Mutation (SNP) | VAF 75/744 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNA1F | c.972C>A p.F324L | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- GEN1 | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 50/525 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- PGGHG | c.821G>T p.G274V | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.137); called by muse, mutect2
- PIEZO2 | c.392T>A p.I131N | Missense Mutation (SNP) | VAF 30/280 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- SIGLEC12 | c.907A>T p.T303S (on ENST00000291707 / NM_053003.4; = p.T185S on NM_033329.2) | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.952); called by muse, mutect2
- STIM1 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 60/583 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TFE3 | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 21/317 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- GP1BA | c.871C>T p.L291= | Silent (SNP) | VAF 60/541 reads (11%) | catalogued as rs770059537; called by muse, mutect2, varscan2
- GRHPR | c.789T>A p.I263= | Silent (SNP) | VAF 28/243 reads (12%) | called by muse, mutect2, varscan2
- MRPS18B | c.603A>G p.P201= | Silent (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2, varscan2
- SULT4A1 | c.318C>T p.R106= | Silent (SNP) | VAF 11/128 reads (9%) | called by muse, mutect2
- TNN | c.3393A>G p.E1131= | Silent (SNP) | VAF 36/346 reads (10%) | catalogued as rs1216912468; called by muse, varscan2
- AC093791.1 | n.391C>A | RNA (SNP) | VAF 4/27 reads (15%) | catalogued as rs1325781462; called by muse, mutect2, varscan2
- PUM1 | chr1:31065717 T>A | 5'Flank (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
